Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FU, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FU-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name: _____	Accession #: _____
MRN: _____	Collected: _____
DOB: _____	Received: _____
Gender: M	Reported: _____
HCN: _____	
Ordering MD: _____	
Copy To: _____	

1CD-0-3
carcinoma, papillary, follicular variant
8340/3

Specimen(s) Received

1. Thyroid: Total thyroidectomy-stitch marks Lt. superior

Site: thyroid, NOS 673.9 10/2/12

Diagnosis

Multifocal bilateral and isthmic papillary carcinoma, dominant 4.2 cm, left; underlying mild nodular hyperplasia: Thyroid
No pathological diagnosis: Parathyroid, right
- Total thyroidectomy specimen

Synoptic Data

Specimen Type:	Total Thyroidectomy
Tumour Focality:	Multifocal
_____ Dominant Tumour _____	
Histologic Type:	Papillary carcinoma, follicular variant 29% pT3
Tumour Site:	Left Lobe
Tumour Size:	Greatest Dimension: 4.2 cm
	Additional Dimensions: 3.3 x 3.0 cm
Capsular Invasion:	Unencapsulated
	Locally invasive
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 0.1 mm
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
_____ Secondary Tumour _____	
Histologic Type:	Papillary carcinoma, follicular variant
Tumour Site:	Isthmus
Tumour Size:	Greatest Dimension: 3.9 cm
	Additional Dimensions: 2.6 x 2.2 cm
Capsular Invasion:	Encapsulated
	Widely invasive
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Indeterminate

Pathologic Staging (pTNM): pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
pNX: Regional lymph nodes cannot be assigned

[page 2 of 2]
Surgical Pathology Consultation Report

Additional Pathologic Findings: pMX: Distant metastasis cannot be assessed
Nodular hyperplasia
Other (specify): additional multiple papillary microcarcinomas

Electronically verified by:

Gross Description

The specimen labeled with the patient's name and as "Thyroid: Total thyroidectomy" consists of a thyroid gland that weighs 66.7 g. The right lobe measures 7.5 cm SI x 3.0 cm ML x 1.1 cm AP, the left lobe measures 5.6 cm SI x 4.0 cm ML x 3.0 cm AP and the isthmus measures 4.0 cm SI x 2.6 cm ML x 2.2 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The upper pole of the right lobe contains a well delineated nodule that measures 0.9 cm SI x 0.9 cm ML x 0.8 cm AP. The upper to lower pole of the left lobe contains a well delineated mass that measures 4.2 cm SI x 3.3 cm ML x 3.0 cm AP. The isthmus contains a well delineated nodule that measures 3.9 cm SI x 2.6 cm ML x 2.2 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of left lobe nodule and normal tissue are stored frozen. Representative sections are submitted as follows:

- 1A-H right lobe, superior to inferior
- 1I-M isthmus
- 1N-V left lobe, superior to inferior

Price/Malignancy History		

Source: NCI Genomic Data Commons file cd4d9d82-700a-436a-a4e9-4fd64e25444f (TCGA-EM-A4FU.429B4980-1DBE-4AF8-AB51-5F36BCC25940.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).